Gene-level copy-number profile of tumor specimen TCGA-BR-4363-01A from TCGA case TCGA-BR-4363, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; Tumor grade: G3; Age at diagnosis: 60.8 years (22,196 days).
Specimen TCGA-BR-4363-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.281b1af4-da1a-4399-ab5e-d67ec57a2bfb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-4363-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a5520fd0-afb4-4bef-a100-876fa8b3580a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 2,941; copy number 2: 52,381; copy number 3: 2,941; copy number 4: 1,534.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-4363-01A-01D-1155-01): tumor purity 0.63, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:35,638,945–37,183,689, 22 genes (within-gene range 0–1): ARPP21, ARPP21-AS1, MIR128-2, AC104308.1, RFC3P1, STAC, NBPF21P, RN7SKP227, DCLK3, HSPD1P6, LINC02033, AC105749.1, TRANK1, AC011816.1, RNU6ATAC4P, AC011816.2, PRADC1P1, EPM2AIP1, MLH1, RPL29P11, LRRFIP2, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,941. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
